Somatic mutation profile of tumor specimen TCGA-AN-A04A-01A (aliquot TCGA-AN-A04A-01A-21W-A050-09) from TCGA case TCGA-AN-A04A, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 36.8 years (13,445 days).
Specimen TCGA-AN-A04A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc2a9d28-f6bd-4b6b-bcc2-05c1eaf56dca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A04A-10A (Blood Derived Normal), aliquot TCGA-AN-A04A-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba4e57dc-c15b-4282-90dd-e9ace6fb9d2b

The open-access MAF lists 39 somatic variants for this specimen: 27 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 22, Silent 12, Nonsense Mutation 3, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGO4 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 4/83 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.13); catalogued as COSV100942848; called by muse, mutect2
- AOC2 | c.2189G>A p.C730Y (on ENST00000253799 / NM_009590.4; = p.C703Y on NM_001158.5) | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99520052; called by muse, mutect2
- ATRX | c.1205T>A p.I402N | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV64881908, COSV64883711; called by muse, mutect2, varscan2
- CCDC102B | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs368864406; called by muse, varscan2
- CDC42BPA | c.5062G>A p.G1688R (on ENST00000334218 / NM_001366019.2; = p.G1675R on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143404397; called by muse, mutect2, varscan2
- FANCA | c.3157C>T p.R1053C | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs376103033; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GGT1 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs779028206, COSV50644290; called by muse, mutect2, varscan2
- H1-2 | c.636_638del p.K213del | In Frame Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs1198017017; called by pindel, varscan2
- IL1R2 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 36/378 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769630697, COSV60207166; called by muse, mutect2
- KCNG4 | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs267604663; called by muse, mutect2, varscan2
- KIT | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs386833402, COSV55395523, COSV55416006; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MOV10L1 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781329843, COSV53170216; called by muse, mutect2, varscan2
- MROH2B | c.2969C>T p.S990F | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as rs767098114, COSV68188468; called by muse, mutect2, varscan2
- MRTFA | c.472C>T p.Q158* | Nonsense Mutation (SNP) | VAF 43/117 reads (37%) | catalogued as COSV62936144; called by muse, mutect2, varscan2
- MYH4 | c.3418C>T p.R1140C | Missense Mutation (SNP) | VAF 100/139 reads (72%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs769526708, COSV55122774, COSV99701250; called by muse, mutect2, varscan2
- NCKAP1 | c.1564C>T p.H522Y | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100720081; called by muse, mutect2, varscan2
- NDUFA1 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as CM070206, COSV65097731; called by muse, mutect2, varscan2
- OR5R1 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs771732923, COSV56573385; called by muse, mutect2, varscan2
- PIK3CB | c.2302C>T p.L768F | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.41); catalogued as rs1316933213, COSV56689313; called by muse, mutect2, varscan2
- SEMA5B | c.3191G>A p.R1064H | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.873); catalogued as rs534828389, COSV52106261; called by muse, mutect2, varscan2
- SH3GL2 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV66052455, COSV66054279; called by muse, mutect2, varscan2
- SINHCAF | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 13/365 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100530514, COSV61797778; called by muse, mutect2
- THAP12 | c.1247G>A p.G416D | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV52612678; called by muse, mutect2, varscan2
- TRABD2A | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as rs1201801674, COSV59105459; called by muse, mutect2, varscan2
- USP7 | c.2317C>T p.P773S | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.036); catalogued as COSV61216830; called by muse, mutect2
- YTHDC1 | c.1394G>A p.W465* (on ENST00000344157 / NM_001031732.4; = p.W447* on NM_133370.4) | Nonsense Mutation (SNP) | VAF 18/280 reads (6%) | catalogued as COSV100704642; called by muse, mutect2
- GATA3 | c.1254_1261del p.P419Dfs*85 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel, varscan2
- ALK | c.4632C>T p.N1544= | Silent (SNP) | VAF 25/143 reads (17%) | catalogued as COSV66561531, COSV66583106; called by muse, mutect2, varscan2
- CYP4F2 | c.480G>T p.L160= | Silent (SNP) | VAF 283/940 reads (30%) | catalogued as COSV50002448; called by muse, mutect2, varscan2
- DOC2A | c.297C>T p.Y99= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as rs767876453, COSV58752486; called by muse, mutect2, varscan2
- GRK3 | c.2019G>T p.V673= | Silent (SNP) | VAF 8/147 reads (5%) | catalogued as COSV100151284; called by muse, mutect2
- LAPTM5 | c.477C>T p.P159= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs1412749825, COSV99612259; called by muse, mutect2
- LRP12 | c.1281T>C p.Y427= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as rs770451385, COSV99407411; called by muse, mutect2, varscan2
- MROH2B | c.3753C>T p.S1251= | Silent (SNP) | VAF 46/206 reads (22%) | catalogued as COSV68188464; called by muse, mutect2, varscan2
- NPTXR | c.1167G>A p.R389= | Silent (SNP) | VAF 44/96 reads (46%) | catalogued as COSV60729343; called by muse, mutect2, varscan2
- OLFML3 | c.798C>T p.Y266= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs959841812, COSV57436690; called by muse, mutect2, varscan2
- PSMD14 | c.15T>G p.L5= | Silent (SNP) | VAF 64/302 reads (21%) | catalogued as COSV68833768; called by muse, mutect2, varscan2
- SYNE1 | c.3264C>T p.L1088= (on ENST00000367255 / NM_182961.4; = p.L1095= on NM_033071.3) | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as COSV55096117; called by muse, mutect2
- ZCRB1 | c.486T>C p.P162= | Silent (SNP) | VAF 23/476 reads (5%) | catalogued as COSV99861205; called by muse, mutect2
